Somatic mutation profile of tumor specimen TCGA-SX-A7SL-01A (aliquot TCGA-SX-A7SL-01A-11D-A34Z-10) from TCGA case TCGA-SX-A7SL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.1 years (27,063 days).
Specimen TCGA-SX-A7SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 231537a8-fa58-46f6-b4c5-046fa348dd4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SL-10A (Blood Derived Normal), aliquot TCGA-SX-A7SL-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cec8eb39-7374-4da6-b3e2-8ae62a00644d

The open-access MAF lists 97 somatic variants for this specimen: 77 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 18, Frame Shift Del 12, In Frame Del 4, Splice Site 2, Frame Shift Ins 2, Nonsense Mutation 1, Nonstop Mutation 1, 5'UTR 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI2 | c.1189C>G p.P397A (on ENST00000295851 / NM_001375719.1; = p.P330A on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV99651639; called by muse, mutect2
- ANOS1 | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs746075352, COSV99390674; called by muse, varscan2
- ASIC5 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs771130277, COSV101539725; called by muse, mutect2, varscan2
- ATP8A1 | c.2804A>T p.D935V | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100045559; called by muse, mutect2, varscan2
- BCDIN3D | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV100445493; called by muse, mutect2, varscan2
- BIRC6 | c.1947G>T p.M649I | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV101428047, COSV70203883; called by muse, mutect2, varscan2
- CCDC141 | c.2969T>A p.L990* | Nonsense Mutation (SNP) | VAF 139/313 reads (44%) | catalogued as COSV99836500; called by muse, mutect2, varscan2
- CD164 | c.268T>A p.Y90N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV99248725; called by muse, mutect2, varscan2
- CDH22 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100952803; called by muse, mutect2, varscan2
- CHAMP1 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100778758; called by muse, mutect2, varscan2
- CRAMP1 | c.3103G>A p.G1035S | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV99245805; called by muse, mutect2, varscan2
- DAPK1 | c.2606C>G p.P869R | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100801424; called by muse, mutect2, varscan2
- FCSK | c.1090G>C p.G364R | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV99850662; called by muse, mutect2, varscan2
- FIZ1 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV55607539, COSV99684515; called by muse, mutect2, varscan2
- FRMD4A | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99198455; called by muse, mutect2, varscan2
- GCFC2 | c.1710G>T p.W570C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100319470; called by muse, mutect2, varscan2
- GOLGB1 | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.675); catalogued as COSV100510545; called by muse, mutect2, varscan2
- GPR173 | c.574A>C p.M192L | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV100212139, COSV100212439; called by muse, mutect2, varscan2
- IGLL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 36/40 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99968564; called by muse, mutect2, varscan2
- ITPR2 | c.5835C>A p.N1945K | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101189900, COSV101190075; called by muse, mutect2, varscan2
- KANK2 | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100763105; called by muse, mutect2
- KIF5A | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1203347152, COSV99672714; called by muse, mutect2, varscan2
- KIFBP | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100741370; called by muse, mutect2, varscan2
- KLC4 | c.922A>G p.R308G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52434393; called by muse, mutect2, varscan2
- LMX1B | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100826974; called by muse, mutect2, varscan2
- LRRC58 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 114/225 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1314334021, COSV99820123; called by muse, mutect2, varscan2
- LYST | c.8269G>A p.A2757T | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs775810592, COSV101088800, COSV67707556; called by muse, mutect2, varscan2
- MAGI2 | c.3929T>A p.L1310H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as COSV100833858; called by muse, mutect2
- MAML3 | c.3010C>G p.Q1004E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101558380; called by muse, mutect2, varscan2
- MAPK6 | c.2165A>T p.*722Lext*24 | Nonstop Mutation (SNP) | VAF 39/103 reads (38%) | catalogued as COSV55931954, COSV99959047; called by muse, mutect2, varscan2
- MCPH1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765564; called by muse, mutect2
- MED13 | c.5419T>A p.C1807S | Missense Mutation (SNP) | VAF 102/173 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101180905; called by muse, mutect2, varscan2
- MPG | c.796C>A p.H266N | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99549855; called by muse, mutect2, varscan2
- MTMR14 | c.1342del p.L448Wfs*112 (on ENST00000296003 / NM_001077525.3; = p.L448Wfs*35 on NM_022485.5) | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as COSV56007572; called by mutect2, pindel, varscan2
- MUC6 | c.5225C>T p.T1742M | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs372353242, COSV101424324; called by muse, mutect2, varscan2
- MYT1 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100114304; called by muse, mutect2, varscan2
- NABP1 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100323025; called by muse, mutect2, varscan2
- NABP2 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs1325316043, COSV57212138, COSV99910428; called by muse, mutect2, varscan2
- NCAPD3 | c.4271C>T p.T1424M | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54453833; called by muse, mutect2, varscan2
- NRDE2 | c.2651A>G p.D884G | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs1193391851, COSV100583361; called by muse, mutect2, varscan2
- OR2M4 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as COSV100141075; called by muse, mutect2
- PAK3 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99456883; called by muse, mutect2, varscan2
- PARP10 | c.2462A>T p.E821V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781860987, COSV100477881; called by muse, mutect2, varscan2
- PCDH10 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52098833, COSV99993259; called by muse, mutect2, varscan2
- PCDH15 | c.5181G>A p.M1727I (on ENST00000644397 / NM_001354429.2; = p.M1669I on NM_001142771.2) | Missense Mutation (SNP) | VAF 108/205 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100903608; called by muse, mutect2, varscan2
- PEX11B | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as rs369527712; called by muse, mutect2, varscan2
- PKHD1 | c.2307G>C p.E769D | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100582208, COSV61868593; called by muse, mutect2, varscan2
- PPAN | c.342+1G>C p.X114_splice | Splice Site (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99461089; called by muse, mutect2, varscan2
- PSMC5 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99856310; called by muse, mutect2, varscan2
- PUM2 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV100163386; called by muse, mutect2
- PXDN | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99412880; called by muse, mutect2, varscan2
- RANBP1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100082101; called by muse, mutect2, varscan2
- RPGRIP1L | c.2919_2920insT p.K974* | Frame Shift Ins (INS) | VAF 79/164 reads (48%) | catalogued as COSV100046086; called by mutect2, pindel, varscan2
- SGSM2 | c.2918_2920del p.I973del (on ENST00000426855 / NM_001098509.2; = p.I1018del on NM_014853.3) | In Frame Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs751168239; called by pindel, varscan2
- SRPK1 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100644302; called by muse, mutect2, varscan2
- SRPK1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1195471249, COSV100644303; called by muse, mutect2, varscan2
- TMEM106A | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100357756; called by muse, mutect2, varscan2
- TMEM52 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1225244371, COSV100205507; called by muse, mutect2
- TRIM65 | c.978_979del p.W327Afs*9 | Frame Shift Del (DEL) | VAF 36/75 reads (48%) | catalogued as rs372788583; called by pindel, varscan2
- UGT2A1 | c.700T>A p.Y234N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99684083; called by muse, mutect2
- WWP1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 102/191 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.529); catalogued as COSV99615982; called by muse, mutect2, varscan2
- ZMYND19 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99483434; called by muse, mutect2, varscan2
- ABHD3 | c.280del p.L94Cfs*67 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1276+1G>C p.X426_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- CDCP2 | c.780del p.Y261Tfs*50 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | called by mutect2, pindel, varscan2
- CLEC1A | c.42_49del p.D14Efs*103 | Frame Shift Del (DEL) | VAF 39/101 reads (39%) | called by mutect2, pindel, varscan2
- DET1 | c.723_731del p.F242_V244del (on ENST00000268148 / NM_001144074.3; = p.F253_V255del on NM_017996.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- DPF1 | c.1065_1067del p.P356del | In Frame Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- JPT2 | c.92del p.P31Qfs*54 | Frame Shift Del (DEL) | VAF 45/85 reads (53%) | called by mutect2, pindel, varscan2
- MIOS | c.888del p.Y296* | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- NF2 | c.452del p.G151Vfs*23 | Frame Shift Del (DEL) | VAF 88/127 reads (69%) | called by mutect2, pindel, varscan2
- NXPH4 | c.535_539del p.T179Rfs*58 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, pindel, varscan2
- PPM1G | c.1601del p.N534Mfs*112 | Frame Shift Del (DEL) | VAF 89/230 reads (39%) | called by mutect2, pindel, varscan2
- SGSM2 | c.2056_2063del p.T686Hfs*37 (on ENST00000426855 / NM_001098509.2; = p.T731Hfs*37 on NM_014853.3) | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- WDR35 | c.3289del p.L1097Sfs*14 (on ENST00000345530 / NM_001006657.2; = p.L1086Sfs*14 on NM_020779.4) | Frame Shift Del (DEL) | VAF 87/243 reads (36%) | called by mutect2, pindel, varscan2
- WDR81 | c.3890_3891insA p.S1297Rfs*42 (on ENST00000409644 / NM_001163809.2; = p.S246Rfs*42 on NM_152348.4) | Frame Shift Ins (INS) | VAF 13/29 reads (45%) | called by mutect2, pindel*, varscan2
- ZNF30 | c.1833_1838del p.K612_V613del | In Frame Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.2100A>G p.P700= (on ENST00000352432; = p.P666= on NM_001683.5) | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100659897; called by muse, mutect2, varscan2
- CASP4 | c.921G>A p.T307= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs552187293, COSV67744642; called by muse, mutect2, varscan2
- CD209 | c.915G>A p.L305= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- CLIP4 | c.2073C>A p.T691= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV100191670; called by muse, mutect2, varscan2
- COX7A1 | c.210C>T p.S70= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV99497046; called by muse, mutect2, varscan2
- EPHA8 | c.516T>C p.S172= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs570237058, COSV99384541; called by muse, mutect2, varscan2
- GFM1 | c.33T>G p.A11= | Silent (SNP) | VAF 63/130 reads (48%) | catalogued as COSV99962792; called by muse, mutect2, varscan2
- GPN3 | c.24C>T p.V8= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs745869616, COSV99959783; called by muse, mutect2, varscan2
- MYO18A | c.2529G>T p.A843= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100572066; called by muse, mutect2
- OR4C13 | c.888T>C p.I296= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV101634154; called by muse, mutect2, varscan2
- PDIA5 | c.1359T>C p.A453= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV100299268; called by muse, mutect2, varscan2
- SEC16A | c.3990T>C p.D1330= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV99257028; called by muse, mutect2, varscan2
- SGSM3 | c.1575G>A p.L525= | Silent (SNP) | VAF 38/42 reads (90%) | catalogued as rs781642937, COSV99960251; called by muse, mutect2, varscan2
- SNRPB2 | c.399T>C p.N133= | Silent (SNP) | VAF 123/198 reads (62%) | catalogued as COSV99855835; called by muse, mutect2, varscan2
- SYS1 | c.285T>A p.T95= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV99713803; called by muse, mutect2, varscan2
- TBC1D4 | c.2472G>A p.E824= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as rs762449836, COSV100884562; called by muse, mutect2, varscan2
- TIAM1 | c.438C>T p.G146= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99733970; called by muse, mutect2, varscan2
- TKT | c.1305T>C p.A435= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99964936; called by muse, mutect2, varscan2
- ACSF2 | c.-1C>G | 5'UTR (SNP) | VAF 15/173 reads (9%) | catalogued as COSV100306005; called by muse, mutect2
- GZMM | c.*5del | 3'UTR (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel
